Somatic mutation profile of tumor specimen 0DU9MV from CCDI case PBCKRR, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Ependymoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 2.8 years (1,016 days).
Specimen 0DU9MV: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 41041c00-f929-4c70-a723-b7bf11a8db96.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DU9NC (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/63e535f9-b6c5-415c-9c7a-d6be90858d38

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NXF3 | c.28G>T p.G10C | Missense Mutation (SNP) | VAF 654/1634 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV67702656; called by muse, varscan2
- CDV3 | c.627-3T>A | Splice Region (SNP) | VAF 50/448 reads (11%) | called by muse, varscan2
- TGDS | c.250A>C p.K84Q | Missense Mutation (SNP) | VAF 278/668 reads (42%) | SIFT tolerated (0.21); PolyPhen benign (0.162); called by muse, varscan2
